Somatic mutation profile of tumor specimen HTMCP-03-06-02062-01A (aliquot HTMCP-03-06-02062-01A-01D-4427) from CGCI case HTMCP-03-06-02062, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 51.3 years (18,734 days).
Specimen HTMCP-03-06-02062-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6785d35d-4fd2-460e-9c52-80278a49e823.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02062-10A (Blood Derived Normal), aliquot HTMCP-03-06-02062-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eee2314-43a8-4023-81ff-e1b002e6281a

The open-access MAF lists 52 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 6, Frame Shift Del 2, RNA 2, 5'Flank 1, Frame Shift Ins 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC8 | c.692G>T p.W231L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM160101, COSV56848804; called by muse, mutect2, varscan2
- ALPK3 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.026); catalogued as rs199572606; called by muse, mutect2, varscan2
- ARHGAP23 | c.3037C>T p.R1013* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs1441229386; called by muse, mutect2, varscan2
- COL27A1 | c.2746G>A p.G916S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61920987; called by muse, mutect2, varscan2
- FBXW7 | c.2033C>G p.S678* (on ENST00000281708 / NM_001349798.2; = p.S598* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 47/175 reads (27%) | catalogued as COSV55897853; called by muse, varscan2
- FOXRED2 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs756741928, COSV53399894; called by muse, mutect2, varscan2
- GPC3 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.634); catalogued as COSV63669007; called by muse, mutect2, varscan2
- ITGB1BP2 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs755426204, COSV99339249; called by muse, mutect2, varscan2
- KANSL1 | c.2558G>A p.R853K (on ENST00000574590 / NM_001193465.2; = p.R854K on NM_015443.4) | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs753288133; called by muse, mutect2, varscan2
- LAMC1 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.998); catalogued as rs746484378, COSV51134667; called by muse, mutect2, varscan2
- NLRC5 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs768062905, COSV52648369; called by muse, mutect2, varscan2
- NXN | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100402794; called by muse, mutect2, varscan2
- PLXNB1 | c.3160C>T p.R1054W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as rs1284299651, COSV56494082; called by muse, mutect2, varscan2
- TP63 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 71/109 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53201679, COSV53221781; called by muse, mutect2, varscan2
- TRAFD1 | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV57506098; called by mutect2, varscan2
- ZNF182 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV100527080; called by muse, mutect2, varscan2
- ABCA1 | c.4092C>G p.F1364L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AHI1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- APOBEC3G | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CNTNAP5 | c.3244A>T p.K1082* | Nonsense Mutation (SNP) | VAF 47/235 reads (20%) | called by muse, mutect2, varscan2
- FAM111B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- HECTD4 | c.13158C>G p.F4386L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2
- ITGA2 | c.1936C>G p.Q646E | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.396); called by muse, mutect2
- JAK2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KCND2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KMT2C | c.5907_5908del p.P1970* | Frame Shift Del (DEL) | VAF 86/237 reads (36%) | called by pindel, varscan2
- MAGI1 | c.3263dup p.S1089Ffs*21 (on ENST00000402939 / NM_001033057.2; = p.S1118Ffs*21 on NM_004742.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 26/125 reads (21%) | called by mutect2, pindel, varscan2
- MYO9B | c.3461G>C p.R1154T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCM1 | c.5634A>T p.E1878D | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCSK5 | c.5262_5263insTTTTAAAATAACT p.L1755Ffs*2 | Nonsense Mutation (INS) | VAF 32/203 reads (16%) | called by mutect2, pindel, varscan2
- PDHA1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- PPRC1 | c.3490G>A p.E1164K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKCI | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2
- RRBP1 | c.956del p.G319Afs*74 | Frame Shift Del (DEL) | VAF 47/204 reads (23%) | called by pindel, varscan2
- TMC7 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- YLPM1 | c.4211G>C p.R1404T | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF607 | c.1290C>A p.F430L | Missense Mutation (SNP) | VAF 56/279 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- BCOR | c.2631C>T p.T877= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs780203470, COSV60703314, COSV60709271; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCAF8L2 | c.756G>A p.V252= | Silent (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- DLGAP3 | c.672C>T p.H224= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV52395269; called by muse, mutect2
- EIF3A | c.4065A>T p.S1355= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- MYT1L | c.2937G>A p.A979= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs755973131, COSV67701680; called by muse, mutect2, varscan2
- PCDH12 | c.138C>T p.I46= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs144137657; called by muse, mutect2, varscan2
- SCN3A | c.819G>A p.L273= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as rs1350547141; called by muse, mutect2, varscan2
- TBX22 | c.387G>A p.V129= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as rs1448685350; called by muse, mutect2, varscan2
- ZMAT1 | c.732G>A p.K244= | Silent (SNP) | VAF 60/238 reads (25%) | catalogued as COSV65660090; called by muse, mutect2, varscan2
- CASKIN2 | c.930+16C>T | Intron (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- KSR1P1 | n.77C>T | RNA (SNP) | VAF 4/43 reads (9%) | catalogued as rs952130155; called by muse, varscan2
- LINC01666 | n.249G>T | RNA (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- RBM34 | chr1:235161319 C>T | 5'Flank (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100783979; called by muse, mutect2, varscan2
